CPTAC case C3N-02972 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c9db5547-a37a-4556-92a6-fcc6a8837377

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1942; Vital status: Dead; Days to death: 905 days (2.5 years); Year of death: 2020; Cause of death: Not Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Corpus uteri; Age at diagnosis: 74.8 years (27,311 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T1b; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC1; FIGO stage: Stage III; Tumor grade: G2; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 905 days (2.5 years); Progression or recurrence: no; Days to last follow up: 905 days (2.5 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4.1 cm; Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 22; Margin status: Uninvolved.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (5 entries)
- Days to follow up: 293 days; Disease response: Tumor Free.
- Days to follow up: 874 days (2.4 years); Disease response: Tumor Free.
- Days to follow up: 905 days (2.5 years); Disease response: Tumor Free.
- Days to follow up: 1,202 days (3.3 years); Disease response: Complete Response.
- Days to follow up: 1,202 days (3.3 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 88.45 kg; Height: 152.4 cm; BMI: 38.08.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02972-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 42 days; Initial weight: 214 mg; Time between excision and freezing: 20 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02972-21: Section location: Anterior and posterior involves entire cavity; Percent tumor nuclei: 85; Percent necrosis: 2.
- Sample C3N-02972-11: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 42 days; Time between excision and freezing: 20 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-02972-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 42 days; Method of sample procurement: Blood Draw.
